Somatic mutation profile of tumor specimen BA2523D (aliquot aq-BA2523D) from BEATAML1.0 case 2225, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.8 years (17,109 days).
Specimen BA2523D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0117c729-993c-4013-824e-061fe43761f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2988D (Solid Tissue Normal), aliquot aq-BA2988D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6445834-5059-45be-b713-6c0bc31fa2d4

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 30/108 reads (28%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- PCDHB4 | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as rs782065445; called by muse, mutect2, varscan2
- USO1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772397784, COSV53705126; called by muse, mutect2, varscan2
- ARHGEF12 | c.3275C>A p.T1092K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- METTL25 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- MYO10 | c.1393C>G p.H465D | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NDST4 | c.1866C>A p.S622R | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NKX3-2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.027); called by muse, varscan2
- MYO16 | c.46C>A p.R16= | Silent (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- RYR2 | c.13080C>T p.S4360= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs369964660, COSV100772573; ClinVar: likely benign; called by mutect2, varscan2
- POLD2 | chr7:44123520 C>T | 5'Flank (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
